Somatic mutation profile of tumor specimen TCGA-A3-3322-01A (aliquot TCGA-A3-3322-01A-01W-0886-08) from TCGA case TCGA-A3-3322, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 51.3 years (18,754 days).
Specimen TCGA-A3-3322-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76ff21c1-b957-4bfd-bc02-5f5daf0f2253.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3322-11A (Solid Tissue Normal), aliquot TCGA-A3-3322-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5bf0d842-6588-4997-bbfe-e0f44b87f302

The open-access MAF lists 75 somatic variants for this specimen: 53 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 21, Frame Shift Del 6, Frame Shift Ins 3, Splice Site 2, Nonsense Mutation 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY8 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.106); catalogued as rs753815200, COSV53913774; called by muse, mutect2, varscan2
- ATAD2B | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV53206368; called by muse, mutect2, varscan2
- DNAH5 | c.4225C>A p.L1409I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.874); catalogued as rs1175342095, COSV99451278; called by mutect2, varscan2
- EVC | c.1920del p.L641Cfs*19 | Frame Shift Del (DEL) | VAF 14/53 reads (26%) | catalogued as COSV53832570; called by mutect2, pindel, varscan2
- FOXN1 | c.1816G>A p.G606R | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.203); catalogued as rs528722201; called by muse, mutect2, varscan2
- IL12RB2 | c.2304G>C p.K768N | Missense Mutation (SNP) | VAF 62/312 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs769927347, COSV52022744; called by muse, mutect2, varscan2
- LYST | c.6781C>T p.R2261C | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.945); catalogued as rs762117854, COSV67703347; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUP210L | c.3272A>C p.K1091T | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV55153669; called by muse, mutect2, varscan2
- SCG2 | c.1220A>G p.N407S | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs758581464; called by muse, mutect2, varscan2
- TSC2 | c.3871G>A p.V1291I | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs201135184; ClinVar: not provided / likely benign / benign; called by muse, mutect2, varscan2
- YME1L1 | c.583G>C p.D195H (on ENST00000326799 / NM_139312.3; = p.D138H on NM_014263.4) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs143591480; called by muse, mutect2, varscan2
- ZNF616 | c.1436G>A p.R479Q | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs766854899; called by muse, mutect2, varscan2
- ARHGEF10L | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- ARMC5 | c.580_583+17del p.X194_splice | Splice Site (DEL) | VAF 3/25 reads (12%) | called by mutect2*, pindel
- C17orf75 | c.447A>C p.E149D | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCNB3 | c.2739_2740insG p.L914Vfs*10 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | called by mutect2, varscan2
- CDH19 | c.283del p.R95Efs*21 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | called by mutect2, pindel, varscan2
- CDK5RAP2 | c.1362G>T p.E454D | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by mutect2, varscan2
- CNTNAP1 | c.2605G>C p.E869Q | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- ENPEP | c.686_693del p.K229Tfs*4 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by pindel, varscan2
- F5 | c.5240C>T p.P1747L | Missense Mutation (SNP) | VAF 32/294 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- FAM163B | c.79T>C p.Y27H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by mutect2, varscan2
- HHIPL1 | c.1514C>G p.S505C | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HMGN2 | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- HSP90B1 | c.964A>G p.K322E | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- LAD1 | c.1079G>T p.R360L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0); called by mutect2, varscan2
- MLX | c.677C>A p.P226H | Missense Mutation (SNP) | VAF 139/776 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, varscan2
- MPHOSPH10 | c.1340C>G p.P447R | Missense Mutation (SNP) | VAF 77/207 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MSH6 | c.3617C>A p.A1206E | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.81); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MTA3 | c.831C>G p.S277R | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- NGEF | c.205_243del p.I69_P81del | In Frame Del (DEL) | VAF 8/147 reads (5%) | called by mutect2, pindel
- NIT2 | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NRDE2 | c.2105C>T p.T702I | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- NUMA1 | c.25dup p.A9Gfs*14 | Frame Shift Ins (INS) | VAF 25/101 reads (25%) | called by mutect2, pindel, varscan2
- NUP210L | c.3271A>T p.K1091* | Nonsense Mutation (SNP) | VAF 21/72 reads (29%) | called by muse, mutect2, varscan2
- NXPE4 | c.901G>A p.V301I (on ENST00000375478 / NM_001077639.2; = p.V17I on NM_017678.3) | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PBRM1 | c.3663del p.E1222Kfs*5 (on ENST00000296302 / NM_001366071.2; = p.E1197Kfs*5 on NM_018313.5) | Frame Shift Del (DEL) | VAF 17/43 reads (40%) | called by mutect2, pindel, varscan2
- PCNT | c.1108C>A p.Q370K | Missense Mutation (SNP) | VAF 22/339 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.146); called by muse, mutect2
- PFAS | c.571C>A p.L191I | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); called by mutect2, varscan2
- PPP1R13B | c.1727dup p.S577Kfs*15 | Frame Shift Ins (INS) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- PRRC2A | c.3368A>C p.E1123A | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- RAPH1 | c.136A>C p.K46Q | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- RPS3A | c.182G>A p.G61D | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- SDR16C5 | c.710+1G>A p.X237_splice | Splice Site (SNP) | VAF 39/78 reads (50%) | called by muse, mutect2, varscan2
- SF3A1 | c.1113_1156del p.P372Sfs*8 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | called by mutect2*, pindel
- SLC23A1 | c.863C>A p.A288E | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SMARCA4 | c.1093G>C p.E365Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- TACC2 | c.2467del p.L823Yfs*105 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | called by mutect2, pindel, varscan2
- TTC12 | c.230A>C p.E77A | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.01); called by mutect2, varscan2
- UBA5 | c.346C>A p.L116I | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZBTB26 | c.736G>T p.G246C | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.408); called by muse, mutect2
- ZCCHC2 | c.2482A>G p.T828A | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF654 | c.2878A>G p.M960V | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- AGBL4 | c.831C>T p.G277= | Silent (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2
- CCDC151 | c.681C>T p.T227= | Silent (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- CERK | c.261C>T p.H87= | Silent (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- COLEC11 | c.663C>T p.P221= | Silent (SNP) | VAF 11/128 reads (9%) | catalogued as rs199962584, COSV52596090; called by muse, mutect2
- DLGAP1 | c.2577T>C p.P859= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs1351976262, COSV59801098; called by muse, mutect2, varscan2
- ENPP2 | c.2448A>G p.V816= (on ENST00000075322 / NM_001040092.3; = p.V868= on NM_006209.5) | Silent (SNP) | VAF 52/275 reads (19%) | called by muse, mutect2, varscan2
- HELZ | c.1017A>G p.Q339= | Silent (SNP) | VAF 80/403 reads (20%) | called by muse, mutect2, varscan2
- ITIH4 | c.765G>A p.E255= | Silent (SNP) | VAF 7/17 reads (41%) | called by mutect2, varscan2
- KIRREL3 | c.1713G>A p.V571= | Silent (SNP) | VAF 20/102 reads (20%) | called by muse, mutect2, varscan2
- LAD1 | c.1080A>C p.R360= | Silent (SNP) | VAF 6/48 reads (13%) | called by mutect2, varscan2
- MINAR1 | c.927C>T p.N309= | Silent (SNP) | VAF 24/156 reads (15%) | catalogued as rs1236243624; called by muse, mutect2, varscan2
- NRBP1 | c.1107C>A p.I369= | Silent (SNP) | VAF 34/125 reads (27%) | called by muse, mutect2, varscan2
- PRIM2 | c.210C>T p.Y70= | Silent (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
- SGCE | c.375A>T p.T125= (on ENST00000647096; = p.T89= on NM_003919.3) | Silent (SNP) | VAF 23/45 reads (51%) | called by muse, mutect2, varscan2
- SGIP1 | c.123C>T p.P41= | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as rs534433911; called by muse, mutect2
- STX4 | c.243G>A p.Q81= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs1227479272; called by muse, mutect2, varscan2
- TECTB | c.96C>T p.C32= | Silent (SNP) | VAF 12/127 reads (9%) | catalogued as COSV65595845; called by muse, mutect2
- WDTC1 | c.270C>T p.T90= | Silent (SNP) | VAF 45/107 reads (42%) | catalogued as rs748448840; called by muse, mutect2, varscan2
- ZNF33A | c.6C>T p.N2= | Silent (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2, varscan2
- ZNF551 | c.1173T>C p.Y391= | Silent (SNP) | VAF 24/73 reads (33%) | called by muse, mutect2, varscan2
- ZNF615 | c.1644C>T p.G548= | Silent (SNP) | VAF 37/113 reads (33%) | catalogued as rs765689777; called by muse, mutect2, varscan2
- HLA-F | chr6:29726891 G>A | 3'Flank (SNP) | VAF 59/190 reads (31%) | called by muse, mutect2, varscan2
